Gene-level copy-number profile of tumor specimen ALCH-ADZZ-TTP1-A from ALCHEMIST case ALCH-ADZZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.3 years (28,244 days).
Specimen ALCH-ADZZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 00885540-0ca8-4cb9-9a51-fed901accc68.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADZZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/62517a98-2cd8-471a-b8be-d4c107fd2345

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 700; copy number 2: 54,617; copy number 3: 2,846; copy number 4: 122; copy number 5: 77; copy number 6: 15; copy number 7: 1; copy number 8: 3; copy number 10: 5; copy number 19: 1; copy number 31: 2; copy number 40: 3.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,454,665–3,481,113, 1 gene: ARHGEF16.
- chr8:7,793,716–7,795,870, 1 gene: PRR23D3P.
- chr15:21,927,657–21,946,641, 1 gene: NF1P2.
- chr15:22,225,278–22,225,329, 1 gene: MIR1268A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 107 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,539,628–7,592,916, 7 genes, copy number 6: PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P.
- chr8:7,753,682–7,771,988, 3 genes, copy number 40: FAM90A19P, FAM90A9P, FAM90A10P.
- chr8:7,811,720–7,829,053, 3 genes, copy number 8: DEFB107A, DEFB105A, DEFB106A.
- chr9:66,721,158–66,745,929, 3 genes, copy number 10: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr15:21,951,242–22,095,857, 7 genes, copy number 6 (within-gene range 2–10): MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,083,221, 1 gene, copy number 6 (within-gene range 2–6): OR4M2.
- chr15:22,178,107–22,185,402, 2 genes, copy number 10: IGHV1OR15-3, IGHV4OR15-8.
- chr16:32,600,299–33,570,935, 55 genes, copy number 5: AC137800.1, AC137800.2, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2, AC142086.2, IGHV2OR16-5, BCAP31P2, SLC6A10P, AC142086.1, IGHV3OR16-15, IGHV3OR16-6, AC142086.6, AC142086.3, AC142086.5, IGHV1OR16-2, IGHV3OR16-10, AC142086.4, IGHV1OR16-4, IGHV3OR16-8, AC145350.2, AC145350.3, HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr16:33,802,764–33,810,767, 2 genes, copy number 31: IGHV3OR16-12, AC136428.3.
- chr16:33,875,039–33,875,468, 1 gene, copy number 7: AC140658.3.
- chr16:34,013,394–34,013,830, 1 gene, copy number 19: AC133561.2.
- chr16:34,120,470–34,120,677, 1 gene, copy number 5: AC136932.1.
- chr17:59,707,192–59,973,101, 10 genes, copy number 5 (within-gene range 3–5): VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1.
- chr17:60,526,293–60,666,280, 6 genes, copy number 5: AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:61,942,605–62,065,278, 5 genes, copy number 5: MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 700. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
